Gene-level copy-number profile of tumor specimen TCGA-E7-A3X6-01A from TCGA case TCGA-E7-A3X6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 70.0 years (25,584 days).
Specimen TCGA-E7-A3X6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.dc45482d-f985-4e03-acb3-b7d961cbd711.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A3X6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f86c5db6-b21a-48fd-9b10-40d61e4f4dcc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 14,336; copy number 2: 42,063; copy number 3: 3,391.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A3X6-01A-12D-A22Y-01): tumor purity 0.71, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:154,928,460–155,106,651, 10 genes (within-gene range 0–1): PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1.
- chr8:21,908,873–22,048,809, 4 genes (within-gene range 0–1): DOK2, XPO7, NPM2, FGF17.
- chr9:21,967,752–22,214,672, 8 genes (within-gene range 0–1): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,923. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
